Gene-level copy-number profile of tumor specimen HCM-BROD-0097-C15-06A from HCMI case HCM-BROD-0097-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 73.5 years (26,828 days).
Specimen HCM-BROD-0097-C15-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 55511366-23fb-48cc-a722-eaf958e2e498.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0097-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,741 have no estimate.
https://portal.gdc.cancer.gov/files/76a179d0-a676-4483-ac75-cb5b7528aa71

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 698; copy number 2: 8,476; copy number 3: 20,290; copy number 4: 16,721; copy number 5: 5,199; copy number 6: 4,299; copy number 7: 1,536; copy number 8: 1,202; copy number 9: 96; copy number 10: 159; copy number 11: 105; copy number 12: 38; copy number 13: 19; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,542,149–75,590,649, 2 genes (within-gene range 0–2): RPS3AP15, AC108724.1.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr14:19,664,098–19,683,677, 1 gene (within-gene range 0–2): AL512310.4.
- chr14:19,677,644–19,691,194, 4 genes (within-gene range 0–2): AL512310.9, AL512310.7, AL512310.2, ARHGAP42P4.
- chr14:102,865,856–102,865,963, 1 gene (within-gene range 0–2): RNU6-1316P.
- chr18:50,879,080–51,085,045, 5 genes: ME2, Y_RNA, ELAC1, AC091551.1, SMAD4.
- chr19:27,638,483–28,396,428, 18 genes: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,155 genes in 52 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–1,379,032, 107 genes, copy number 8 (broad region; genes not listed).
- chr1:143,875,171–152,115,454, 326 genes, copy number 7–11 (within-gene range 5–11) (broad region; genes not listed).
- chr2:81,418,723–81,666,728, 4 genes, copy number 9: CHMP4AP1, LINC01815, RNA5SP99, AC013262.1.
- chr2:194,344,190–194,761,435, 5 genes, copy number 10: LINC01821, AC106883.1, Metazoa_SRP, AC006196.1, LINC01790.
- chr4:2,139,673–2,262,109, 4 genes, copy number 7: AL136360.2, COX6B1P5, MXD4, MIR4800.
- chr5:34,373,028–39,889,059, 89 genes, copy number 7–9 (broad region; genes not listed).
- chr5:42,188,266–43,886,628, 44 genes, copy number 7: AC108099.1, GHR, SERBP1P6, AC093225.1, AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1.
- chr5:163,709,210–163,887,827, 4 genes, copy number 8: AC116917.1, RNU6-168P, AC008432.1, LSM1P2.
- chr5:172,641,263–172,976,374, 16 genes, copy number 8: NEURL1B, AC027309.2, MIR5003, AC027309.1, AC022217.2, AC022217.1, AC022217.3, DUSP1, Y_RNA, AC022217.4, AC110011.1, ERGIC1, AC008429.1, AC008429.3, RPL26L1, AC008429.2.
- chr6:53,001,279–53,349,179, 14 genes, copy number 7 (within-gene range 4–7): CILK1, AL031178.1, FBXO9, AL031178.2, RN7SL244P, AL512347.1, GCM1, RNU6-464P, SOD1P1, AL512378.1, RNU1-136P, HMGB1P20, ELOVL5, MIR5685.
- chr8:46,028,804–47,068,323, 18 genes, copy number 7: AC118650.1, HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32.
- chr8:58,805,412–59,137,502, 5 genes, copy number 11: TOX, RNU4-50P, AC105150.1, AC090152.1, AC087698.1.
- chr8:67,043,079–69,660,915, 29 genes, copy number 8 (within-gene range 5–8): COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1, NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1.
- chr8:69,922,751–71,228,629, 24 genes, copy number 8 (within-gene range 3–8): RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA, AC022858.1.
- chr8:73,420,369–143,563,062, 983 genes, copy number 8–14 (within-gene range 3–14) (broad region; genes not listed).
- chr11:72,410,716–74,009,085, 56 genes, copy number 7–10: AP003785.1, ART2BP, ART2P, AP005019.2, AP005019.1, LINC01537, PDE2A, PDE2A-AS2, MIR139, RNU7-105P, PDE2A-AS1, ARAP1, ARAP1-AS1, AP003065.1, ARAP1-AS2, RPS12P20, STARD10, Y_RNA, MIR4692, AP002381.2, ATG16L2, FCHSD2, RNU6-672P, AP002381.1, AP002761.2, AP002761.1, P2RY2, AP002761.4, OR8R1P, P2RY6, AP002761.3, ARHGEF17, RELT, AP000763.4, FAM168A, AP000763.3, AP000763.1, AP000763.2, HMGN2P38, AP000860.1, PLEKHB1, RAB6A, AP002993.1, AP002770.1, MRPL48, RN7SKP243, CCDC58P5, COA4, PAAF1, ARPC3P4, DNAJB13, AP003717.1, UCP2, AP003717.2, AP003717.3, UCP3.
- chr11:75,717,838–76,444,687, 22 genes, copy number 11: MOGAT2, RN7SL786P, AP001922.1, DGAT2, AP001922.3, AP003031.1, UVRAG-DT, UVRAG, Y_RNA, Y_RNA, PPP1R1AP1, AP003168.2, RNA5SP344, AP003168.1, AP002340.1, WNT11, AP000785.1, LINC02761, THAP12, GVQW3, Y_RNA, AP002360.1.
- chr11:76,694,041–77,215,241, 11 genes, copy number 7–9 (within-gene range 6–9): GUCY2EP, AP003119.1, TSKU, AP003119.2, AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A.
- chr11:129,537,869–130,547,429, 25 genes, copy number 7: RPS27P20, AP003500.1, LINC01395, AP003327.2, AP003327.1, TMEM45B, NFRKB, PRDM10, LINC00167, AP003041.1, ELOBP2, AP003041.2, APLP2, RPL34P21, U4, ST14, ZBTB44, NDUFAF2P2, DDX18P5, RN7SL778P, ZBTB44-DT, ADAMTS8, ADAMTS15, AP004371.1, BAK1P2.
- chr12:389,273–684,127, 8 genes, copy number 7 (within-gene range 4–7): CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455.
- chr12:19,089,151–26,079,892, 104 genes, copy number 7 (broad region; genes not listed).
- chr13:18,467,172–45,436,660, 527 genes, copy number 7 (broad region; genes not listed).
- chr14:49,782,083–49,913,760, 10 genes, copy number 9 (within-gene range 3–9): NEMF, Y_RNA, RNU6-539P, RN7SL3, AL627171.2, RN7SL2, AL627171.1, ARF6, RNU6-189P, Metazoa_SRP.
- chr15:59,372,693–59,689,534, 12 genes, copy number 7 (within-gene range 3–7): FAM81A, NSA2P4, AC092868.1, Y_RNA, AC092754.2, AC092754.1, RNA5SP396, GCNT3, GTF2A2, AC092755.1, BNIP2, PIGHP1.
- chr16:24,472,798–24,911,628, 6 genes, copy number 7: AC008938.1, RBBP6, TNRC6A, LINC01567, AC008731.1, SLC5A11.
- chr16:25,691,959–29,748,299, 137 genes, copy number 7–13 (broad region; genes not listed).
- chr16:34,978,744–35,912,516, 79 genes, copy number 7 (broad region; genes not listed).
- chr16:88,453,280–88,687,278, 9 genes, copy number 8–11: ZFPM1, MIR5189, AC116552.1, ZC3H18, IL17C, CYBA, MVD, SNAI3-AS1, SNAI3.
- chr17:29,929,200–30,117,497, 7 genes, copy number 9 (within-gene range 6–9): EFCAB5, AC104982.3, RNY4P13, AC104996.3, AC104996.1, AC104996.2, AC104984.2.
- chr18:15,056,845–23,026,488, 58 genes, copy number 7–8: AP005242.3, AP005242.1, AP005901.2, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P, ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA.
- chr19:7,112,255–8,514,167, 73 genes, copy number 8 (broad region; genes not listed).
- chr19:9,810,267–10,119,918, 21 genes, copy number 8: FBXL12, SNORA70, RPL10P15, UBL5, AC008752.2, PIN1, OLFM2, COL5A3, AC008742.1, RDH8, C3P1, MIR5589, SHFL, AC020931.1, ANGPTL6, PPAN-P2RY11, PPAN, SNORD105, SNORD105B, P2RY11, EIF3G.
- chr19:22,286,441–23,512,656, 65 genes, copy number 7 (broad region; genes not listed).
- chr19:29,606,283–33,815,763, 80 genes, copy number 7–10 (broad region; genes not listed).
- chr19:34,126,973–34,545,395, 14 genes, copy number 7: CHCHD2P3, LSM14A, GARRE1, RPL29P33, AC010504.1, GPI, AC092073.1, PDCD2L, RN7SL154P, AC008747.1, UBA2, WTIP, RPS26P55, ZNF807P.
- chr19:35,399,511–35,908,295, 47 genes, copy number 7: LINC01531, AC002511.3, RN7SL491P, AC002511.2, AC002511.1, FFAR2, KRTDAP, DMKN, SBSN, GAPDHS, TMEM147-AS1, TMEM147, ATP4A, AD000090.1, LINC01766, AC002115.1, HAUS5, RBM42, ETV2, COX6B1, UPK1A, UPK1A-AS1, TYMSP2, ZBTB32, KMT2B, IGFLR1, AD000671.2, U2AF1L4, PSENEN, AD000671.1, AD000671.3, LIN37, AC002398.2, HSPB6, PROSER3, AC002398.1, ARHGAP33, LINC01529, PRODH2, NPHS1, KIRREL2, APLP1, RN7SL402P, NFKBID, AD000864.1, HCST, TYROBP.
- chr19:36,259,540–36,850,787, 24 genes, copy number 7 (within-gene range 4–7): LINC00665, AC092296.2, ZFP14, AC092296.1, AC092296.4, ZFP82, AC092296.3, ZNF566, AC092295.2, CTBP2P7, ZNF260, AC092295.1, ZNF529, ZNF529-AS1, ZNF382, ZNF461, AC074138.1, LINC01534, ZNF567, ZNF850, AC020928.1, AC020928.2, ZNF790-AS1, ZNF790.
- chr19:37,235,507–37,906,677, 28 genes, copy number 7 (within-gene range 4–7): AC016590.1, LINC01535, ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1, WDR87.
- chr21:7,744,962–8,454,792, 26 genes, copy number 7: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.
- chr22:18,527,802–18,843,399, 14 genes, copy number 10: TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4, FAM230E, GGT3P, AC008132.2, E2F6P1.

Autosomal genes at a single copy (total copy number 1): 681. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
